Gene-level copy-number profile of tumor specimen C3N-02434-01 from CPTAC case C3N-02434, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.2 years (27,102 days).
Specimen C3N-02434-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 46d9b91b-19f4-4931-bd76-95a815eb7cf0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02434-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,259 have no estimate.
https://portal.gdc.cancer.gov/files/4e196769-9509-4725-8c0e-5a3eacc63390

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 632; copy number 2: 21,474; copy number 3: 10,122; copy number 4: 20,656; copy number 5: 2,808; copy number 6: 967; copy number 7: 324; copy number 8: 504; copy number 9: 560; copy number 10: 29; copy number 11: 50; copy number 12: 13; copy number 13: 134; copy number 14: 25; copy number 15: 53; copy number 16: 6; copy number 21: 4.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr21:44,133,610–44,210,114, 1 gene (within-gene range 0–1): GATD3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,212 genes in 52 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:27,309,492–27,988,087, 27 genes, copy number 6 (within-gene range 4–6): MPV17, GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR, C2orf16, ZNF512, AC074091.2, CCDC121, GPN1, AC074091.1, SUPT7L, SLC4A1AP, LINC01460, MRPL33, RBKS.
- chr2:39,082,589–39,128,927, 3 genes, copy number 7: RNU6-198P, HSPE1P13, Y_RNA.
- chr2:39,436,530–71,984,434, 531 genes, copy number 5–21 (within-gene range 4–21) (broad region; genes not listed).
- chr2:87,030,675–87,222,488, 7 genes, copy number 5: ANAPC1P2, ANAPC1P2, AC092651.1, ANAPC1P3, AC083899.1, MIR4771-1, CENPNP1.
- chr2:89,851,791–91,659,972, 44 genes, copy number 5: IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4.
- chr3:139,353,946–198,123,232, 1,003 genes, copy number 5–15 (within-gene range 3–15) (broad region; genes not listed).
- chr4:49,486,926–49,589,529, 11 genes, copy number 7: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:67,417,305–68,376,505, 33 genes, copy number 6: AC104806.2, RNU1-63P, RNA5SP527, AC104806.1, CENPC, STAP1, AC096720.2, UBA6, AC096720.1, UBA6-AS1, ST3GAL1P1, AC079880.1, AC079880.2, GNRHR, SNORA62, TMPRSS11CP, TMPRSS11D, TMPRSS11A, TMPRSS11GP, RNU6-95P, GCOM2, MTND2P41, TMPRSS11F, SYT14P1, FTLP10, TMPRSS11BNL, TMPRSS11B, AC098799.3, AC098799.1, AC098799.2, APOOP4, YTHDC1, MT2P1.
- chr4:68,509,441–68,616,137, 4 genes, copy number 7: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr4:70,397,931–70,532,743, 3 genes, copy number 8: OPRPN, MUC7, AMTN.
- chr4:74,308,470–75,434,449, 18 genes, copy number 6–8: EPGN, EREG, AC021180.1, AREG, AC239584.1, BTC, HSPE1P23, PARM1, PARM1-AS1, AC110760.1, LINC02562, AC110760.2, AC093870.1, AC025244.1, AC025244.2, LINC02483, AC096759.1, AC096759.2.
- chr4:76,214,040–82,044,244, 80 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr6:15,102,946–28,649,538, 316 genes, copy number 5–9 (broad region; genes not listed).
- chr6:35,342,558–35,546,573, 8 genes, copy number 7: PPARD, MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4.
- chr6:36,196,744–60,546,660, 433 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr6:70,667,776–71,652,611, 22 genes, copy number 6–12: SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.1, KRT19P1, RNU4-66P.
- chr6:72,522,641–80,557,189, 119 genes, copy number 5–10 (broad region; genes not listed).
- chr7:52,891,837–62,275,678, 158 genes, copy number 5 (broad region; genes not listed).
- chr7:88,759,700–89,496,918, 3 genes, copy number 5 (within-gene range 3–5): ZNF804B, TEX47, AC002383.1.
- chr8:55,879,835–56,014,169, 4 genes, copy number 8: LYN, AC018607.1, SNORA1B, RN7SL798P.
- chr8:90,592,804–91,398,155, 16 genes, copy number 5: LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7.
- chr9:12,134–118,204, 10 genes, copy number 5: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4.
- chr9:26,066,675–29,826,711, 37 genes, copy number 5: AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr9:35,906,202–40,153,147, 112 genes, copy number 6–9 (broad region; genes not listed).
- chr9:40,992,249–43,045,120, 61 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr9:62,387,171–63,143,401, 30 genes, copy number 6: AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4.
- chr9:63,974,762–66,179,474, 47 genes, copy number 6–11: AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr11:102,047,437–103,479,863, 39 genes, copy number 8–13 (within-gene range 3–13): CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1.
- chr12:18,080,869–45,610,620, 391 genes, copy number 5–6 (broad region; genes not listed).
- chr15:24,558,060–26,477,840, 116 genes, copy number 6 (broad region; genes not listed).
- chr18:3,962,353–5,385,330, 19 genes, copy number 15: DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1.
- chr18:20,946,906–26,657,401, 115 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:26,685,954–26,703,638, 3 genes, copy number 5 (within-gene range 3–5): AC012588.1, PCAT18, U3.
- chr18:77,622,552–77,863,567, 3 genes, copy number 6: AC123786.1, AC123786.2, RNA5SP461.
- chr18:78,795,612–78,928,494, 4 genes, copy number 8: AC044873.1, AC091027.2, AC091027.1, AC091027.3.
- chr18:79,679,803–80,247,514, 18 genes, copy number 5: CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr20:13,714,322–16,053,197, 19 genes, copy number 5 (within-gene range 4–5): ESF1, NDUFAF5, SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.
- chr21:8,603,547–13,016,692, 41 genes, copy number 5–8: RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.
- chr22:15,901,791–46,762,563, 1,225 genes, copy number 5 (broad region; genes not listed).
- chr22:49,718,053–50,801,309, 67 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 632. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
